Somatic mutation profile of tumor specimen 0DLIFR from CCDI case PBBYCD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Occipital lobe; Age at diagnosis: 13.4 years (4,888 days).
Specimen 0DLIFR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6a2ddd8-4aca-45d3-b8dc-1828cc35c78d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLIF6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e46a6d1-8323-4ad9-b712-831267167300

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 6, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, 5'UTR 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 89/254 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- PTEN | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 19/176 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs876660634, CM094222, COSV64293993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.754_756del p.L252del | In Frame Del (DEL) | VAF 276/290 reads (95%) | hotspot (GDC flag); called by mutect2, varscan2
- BRD3 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs200965087; called by muse, mutect2, varscan2
- BRWD3 | c.3368A>G p.Q1123R | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs183157250; called by muse, mutect2, varscan2
- CEP250 | c.3257G>A p.R1086H | Missense Mutation (SNP) | VAF 239/561 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs745957253; called by muse, mutect2, varscan2
- CLSTN3 | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 20/580 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.454); catalogued as rs1335882615; called by muse, mutect2
- CNGA2 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1187225200; called by muse, mutect2, varscan2
- CUL7 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 116/435 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1209334551, COSV54814016; called by muse, mutect2, varscan2
- DCC | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 97/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV104395481, COSV59092158; called by muse, mutect2, varscan2
- DNAH5 | c.11632G>A p.E3878K | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs202140771; called by muse, mutect2, varscan2
- EGR1 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 116/554 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1230522969, COSV53518023; called by muse, mutect2, varscan2
- FASLG | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 201/824 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs780144691; called by muse, mutect2, varscan2
- GPR101 | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV53238740; called by muse, mutect2, varscan2
- HYAL4 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 172/335 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs751222685; called by muse, mutect2, varscan2
- LPAR5 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1024837826, COSV61693072; called by muse, mutect2
- MYPN | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 61/265 reads (23%) | catalogued as rs199476412, CM122963, COSV62731366, COSV62733416; ClinVar: not provided; called by muse, mutect2, varscan2
- NIPBL | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 45/463 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779888500; called by muse, mutect2, varscan2
- NYX | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs746330892; called by muse, mutect2, varscan2
- PDE2A | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 44/301 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771823432; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729dup p.T576dup (on ENST00000521381 / NM_181523.3; = p.T306dup on NM_181504.4) | In Frame Ins (INS) | VAF 144/368 reads (39%) | catalogued as COSV57130212, COSV57141712; called by mutect2, varscan2
- PRSS16 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs773141284, COSV57915108; called by muse, mutect2, varscan2
- PSG9 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 105/169 reads (62%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.557); catalogued as rs1230068127; called by muse, mutect2, varscan2
- PTEN | c.428del p.G143Afs*4 | Frame Shift Del (DEL) | VAF 92/196 reads (47%) | catalogued as CM132265, COSV100911161, COSV64291704; called by mutect2, varscan2
- YLPM1 | c.3725A>G p.Y1242C | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs372595945; called by muse, mutect2, varscan2
- ATRX | c.2447del p.N816Ifs*6 | Frame Shift Del (DEL) | VAF 140/319 reads (44%) | called by mutect2, varscan2
- CACNA1D | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 120/488 reads (25%) | called by muse, mutect2, varscan2
- COLEC10 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CXCR3 | c.941A>C p.N314T | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHF | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 104/246 reads (42%) | called by muse, mutect2, varscan2
- FLT3 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 131/316 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- GRIPAP1 | c.1273A>T p.S425C | Missense Mutation (SNP) | VAF 16/500 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); called by muse, mutect2
- ITGA1 | c.3407T>C p.L1136P | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- NYNRIN | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 38/352 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPARD | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRZ1 | c.5401C>T p.Q1801* | Nonsense Mutation (SNP) | VAF 127/566 reads (22%) | called by muse, mutect2, varscan2
- RNF123 | c.605_608del p.I202Tfs*11 | Frame Shift Del (DEL) | VAF 69/299 reads (23%) | called by mutect2, varscan2
- SOWAHA | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 45/282 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA4 | c.2577G>A p.Q859= | Silent (SNP) | VAF 72/327 reads (22%) | called by muse, mutect2, varscan2
- ADAM29 | c.834G>A p.T278= | Silent (SNP) | VAF 237/248 reads (96%) | catalogued as rs531043841, COSV63668645; called by muse, mutect2, varscan2
- ADAMTS2 | c.2991G>A p.E997= | Silent (SNP) | VAF 237/527 reads (45%) | called by muse, mutect2, varscan2
- KCND1 | c.855C>T p.D285= | Silent (SNP) | VAF 140/310 reads (45%) | called by muse, mutect2, varscan2
- SLC38A4 | c.1293C>G p.L431= | Silent (SNP) | VAF 21/251 reads (8%) | called by muse, mutect2
- TSPOAP1 | c.927C>T p.P309= | Silent (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- GLUD2 | c.-17C>T | 5'UTR (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- MOV10L1 | c.-53C>T | 5'UTR (SNP) | VAF 7/37 reads (19%) | catalogued as rs530867335; called by muse, mutect2, varscan2
- PSMA6 | c.589-79_589-77del | Intron (DEL) | VAF 7/48 reads (15%) | called by mutect2, varscan2
- SMARCA4 | c.2505+80G>C | Intron (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
